Somatic mutation profile of tumor specimen TCGA-AB-2867-03B (aliquot TCGA-AB-2867-03B-01W-0728-08) from TCGA case TCGA-AB-2867, project TCGA-LAML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with maturation; Tissue or organ of origin: Bone marrow; Age at diagnosis: 66.4 years (24,257 days).
Specimen TCGA-AB-2867-03B: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1216ea70-d837-488f-ac38-c0268fb83aba.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AB-2867-11B (Solid Tissue Normal), aliquot TCGA-AB-2867-11B-01W-0729-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c6ac6fbd-2418-4f35-966d-df6ef5c35437

The open-access MAF lists 9 somatic variants for this specimen: 7 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Intron 1, Splice Site 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CENPN | c.553C>T p.H185Y | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as COSV55144317; called by muse, mutect2, varscan2
- GALNT13 | c.421C>A p.R141S | Missense Mutation (SNP) | VAF 11/234 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV67217413, COSV67220468; called by muse, mutect2
- KDM6A | c.1861C>T p.R621C | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as rs139486036, COSV65040238; called by muse, mutect2, varscan2
- KIAA0513 | c.94C>A p.Q32K | Missense Mutation (SNP) | VAF 13/309 reads (4%) | SIFT tolerated, low confidence (0.96); PolyPhen benign (0.006); catalogued as COSV50744846; called by muse, mutect2
- OXA1L | c.343T>G p.F115V (on ENST00000285848; = p.F55V on NM_005015.5) | Missense Mutation (SNP) | VAF 44/151 reads (29%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.003); catalogued as COSV53538739; called by muse, mutect2, varscan2
- PSMB10 | c.329G>A p.G110D | Missense Mutation (SNP) | VAF 79/174 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.654); catalogued as COSV50455764; called by muse, mutect2, varscan2
- PRPF8 | c.5506-2A>T p.X1836_splice | Splice Site (SNP) | VAF 6/52 reads (12%) | called by muse, mutect2
- ZNF675 | c.96G>T p.V32= | Silent (SNP) | VAF 9/153 reads (6%) | catalogued as COSV63095696; called by muse, mutect2
- KALRN | c.4929+8528C>T | Intron (SNP) | VAF 18/74 reads (24%) | catalogued as rs1279526484, COSV53782432; called by muse, mutect2, varscan2
